Somatic mutation profile of tumor specimen TCGA-24-1927-01A (aliquot TCGA-24-1927-01A-01W-0699-08) from TCGA case TCGA-24-1927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.5 years (21,719 days).
Specimen TCGA-24-1927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ee72664-320b-436b-a3d3-f4ba9ac491ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1927-10A (Blood Derived Normal), aliquot TCGA-24-1927-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efb8173c-c99c-435b-bda7-eaf9df2f644d

The open-access MAF lists 104 somatic variants for this specimen: 76 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 27, Nonsense Mutation 5, Frame Shift Del 2, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 122/162 reads (75%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV101037010; called by muse, varscan2
- ABCA1 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101037013; called by muse, varscan2
- ADGRL3 | c.3982G>A p.D1328N (on ENST00000506720 / NM_001322402.2; = p.D1217N on NM_015236.6) | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101541104; called by muse, mutect2, varscan2
- ANKRD49 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100119710; called by muse, mutect2
- ARHGAP31 | c.2221C>A p.P741T | Missense Mutation (SNP) | VAF 177/387 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99957161; called by muse, mutect2, varscan2
- ARSF | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100839514, COSV63839704; called by muse, mutect2, varscan2
- ATPAF2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1568572298, COSV101466944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEND3 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100944612; called by muse, varscan2
- CCDC171 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs777966025, COSV99900746; called by muse, mutect2, varscan2
- CHD2 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV101245300; called by muse, mutect2, varscan2
- CILP | c.3380A>G p.Q1127R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.866); catalogued as COSV99973445; called by muse, mutect2, varscan2
- CLBA1 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV101121047; called by muse, mutect2, varscan2
- CRTAM | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV99912033; called by muse, mutect2
- DCC | c.2227A>G p.M743V | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100500271; called by muse, mutect2, varscan2
- DGKH | c.2234A>C p.N745T | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99818860; called by muse, mutect2, varscan2
- DMWD | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99353184; called by muse, mutect2, varscan2
- DYNC1H1 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794940; called by muse, mutect2
- DYNC1H1 | c.9231C>A p.D3077E | Missense Mutation (SNP) | VAF 164/1047 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100794941; called by muse, mutect2, varscan2
- ENPP2 | c.1491C>G p.Y497* (on ENST00000075322 / NM_001040092.3; = p.Y549* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 91/376 reads (24%) | catalogued as COSV99308349; called by muse, mutect2, varscan2
- EPHA8 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99384895; called by mutect2, varscan2
- FBXO2 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99278942; called by muse, mutect2, varscan2
- FBXW11 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV99440507; called by muse, mutect2, varscan2
- FGFBP2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.543); catalogued as rs150217354; called by muse, mutect2
- GALM | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV99697234; called by muse, mutect2
- GUCA1B | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | catalogued as COSV100027717; called by muse, mutect2, varscan2
- HFE | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 109/417 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as rs781632455, COSV58512658; called by muse, mutect2, varscan2
- HLA-A | c.204G>C p.R68S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); catalogued as COSV100954440; called by muse, mutect2
- ITGA10 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.771); catalogued as rs782262690, COSV65198882; called by muse, mutect2
- ITGB8 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99751550; called by muse, mutect2, varscan2
- KIZ | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99852088; called by muse, mutect2, varscan2
- MAGEA10 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99726732; called by muse, mutect2, varscan2
- MARF1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs200032578; called by muse, mutect2
- MEP1B | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.043); catalogued as COSV99328884; called by muse, mutect2, varscan2
- MGAT3 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV57866421; called by muse, mutect2, varscan2
- MON1B | c.943G>C p.A315P | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99941722; called by muse, mutect2, varscan2
- MROH2B | c.2432G>C p.R811T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as COSV101270684, COSV101270931; called by muse, mutect2, varscan2
- MUC17 | c.5795C>T p.P1932L | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100073408; called by muse, mutect2, varscan2
- MYH15 | c.2279C>A p.S760Y | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV56319856, COSV99843346; called by muse, mutect2, varscan2
- MYH4 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs557134943, COSV55126346; called by muse, mutect2, varscan2
- OR52E2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs745479340, COSV58612078, COSV58612463; called by muse, mutect2, varscan2
- PCDHGC4 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340275; called by muse, mutect2
- PHACTR2 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99991633; called by muse, mutect2, varscan2
- PLD1 | c.1928T>A p.F643Y | Missense Mutation (SNP) | VAF 362/778 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV100578181; called by muse, mutect2, varscan2
- POLD1 | c.2604C>G p.I868M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99569991; called by muse, mutect2, varscan2
- PORCN | c.918C>A p.N306K (on ENST00000326194 / NM_203475.3; = p.N295K on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58225668; called by muse, mutect2
- PPP1R42 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100221280; called by muse, mutect2
- PRPF4B | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV61784698; called by muse, mutect2, varscan2
- RIN2 | c.458A>T p.E153V (on ENST00000255006 / NM_001242581.1; = p.E104V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as COSV99657187; called by muse, mutect2, varscan2
- RNF10 | c.2105G>T p.S702I | Missense Mutation (SNP) | VAF 165/200 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as COSV100378687; called by muse, mutect2, varscan2
- RPS6KB1 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 12/365 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as COSV99847520; called by muse, mutect2
- SEMA3A | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV54860221, COSV99546765; called by muse, mutect2
- SEMA4F | c.2220C>A p.F740L | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100336019; called by muse, mutect2
- SESTD1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs374482722, COSV100090537; called by muse, mutect2, varscan2
- SH3D19 | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100455674; called by muse, mutect2
- SLC7A2 | c.1621G>A p.V541I (on ENST00000494857 / NM_001370338.1; = p.V580I on NM_003046.6) | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs368801565; called by muse, mutect2, varscan2
- SRRD | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99314360, COSV99314628; called by muse, mutect2, varscan2
- SUGP1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53233679, COSV99448717; called by muse, mutect2, varscan2
- TMCO5A | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV100148572, COSV100148592; called by muse, mutect2, varscan2
- TMEM131 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99487823; called by muse, mutect2, varscan2
- TNRC6A | c.4832A>C p.E1611A | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100170050; called by muse, mutect2, varscan2
- TROAP | c.2105G>C p.S702T | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as COSV99226855; called by muse, mutect2
- TTC13 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100792933; called by muse, mutect2
- TTN | c.21041C>T p.P7014L (on ENST00000591111; = p.P6087L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | PolyPhen benign (0.006); catalogued as COSV100614421; called by muse, mutect2, varscan2
- UCK2 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100902988, COSV63316635; called by muse, mutect2
- WEE2 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV101285180, COSV66878222; called by muse, mutect2
- ZBTB47 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99234226; called by muse, mutect2, varscan2
- ZNF461 | c.1329T>G p.C443W | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831422; called by muse, mutect2, varscan2
- ACACA | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- CSPG4 | c.3061C>A p.Q1021K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by mutect2, varscan2
- INSR | c.1318del p.D440Tfs*47 | Frame Shift Del (DEL) | VAF 210/559 reads (38%) | called by mutect2, pindel, varscan2
- MTCL1 | c.3007C>A p.L1003M (on ENST00000306329 / NM_001378206.1; = p.L684M on NM_015210.4) | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by mutect2, varscan2
- SIDT2 | c.726C>G p.S242R | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.219); called by mutect2, varscan2
- VCX | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, varscan2
- VCX3A | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.25); called by muse, varscan2
- ZNF341 | c.1291del p.D431Tfs*34 (on ENST00000375200 / NM_001282935.1; = p.D424Tfs*34 on NM_032819.4) | Frame Shift Del (DEL) | VAF 241/592 reads (41%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1731G>A p.L577= | Silent (SNP) | VAF 18/574 reads (3%) | catalogued as COSV100578681; called by muse, mutect2
- ABCF3 | c.1845G>A p.Q615= | Silent (SNP) | VAF 12/239 reads (5%) | catalogued as COSV53052049; called by muse, mutect2
- ANKRD11 | c.6621C>G p.P2207= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99969414; called by muse, mutect2, varscan2
- ATF6B | c.1371C>G p.S457= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100916825; called by muse, mutect2, varscan2
- BCORL1 | c.4692G>T p.V1564= | Silent (SNP) | VAF 294/462 reads (64%) | catalogued as COSV99499652; called by muse, mutect2, varscan2
- BORCS5 | c.579G>A p.E193= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100056081; called by muse, mutect2, varscan2
- CFAP61 | c.1731G>A p.E577= | Silent (SNP) | VAF 86/301 reads (29%) | catalogued as COSV99844993; called by muse, mutect2, varscan2
- CLMN | c.1422G>A p.Q474= | Silent (SNP) | VAF 18/164 reads (11%) | called by mutect2, varscan2
- CTSA | c.120G>A p.G40= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV99509886; called by muse, varscan2
- DOCK1 | c.1221A>C p.T407= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99729933; called by muse, mutect2, varscan2
- FGD5 | c.2532C>T p.Y844= | Silent (SNP) | VAF 22/536 reads (4%) | catalogued as COSV99548152; called by muse, mutect2
- GABPB2 | c.309G>T p.L103= | Silent (SNP) | VAF 28/418 reads (7%) | catalogued as COSV100927231; called by muse, mutect2
- GATA2 | c.1299G>C p.L433= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV100351332; called by muse, mutect2, varscan2
- GSTA5 | c.558C>G p.T186= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV99489564; called by muse, mutect2, varscan2
- H1-3 | c.447G>A p.K149= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as rs969768818, COSV55098616; called by muse, mutect2, varscan2
- HMCN1 | c.5307G>A p.L1769= | Silent (SNP) | VAF 30/325 reads (9%) | catalogued as COSV99629682; called by muse, mutect2
- LPGAT1 | c.996T>G p.A332= | Silent (SNP) | VAF 95/336 reads (28%) | catalogued as COSV100878133; called by muse, mutect2, varscan2
- MAGEB1 | c.87C>T p.H29= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs369750525, COSV66775520; called by muse, mutect2, varscan2
- MTBP | c.1791A>C p.S597= | Silent (SNP) | VAF 15/227 reads (7%) | catalogued as COSV100012173; called by muse, mutect2
- NEDD4 | c.288A>T p.R96= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101436607; called by muse, mutect2, varscan2
- OR52I2 | c.354A>G p.G118= | Silent (SNP) | VAF 261/471 reads (55%) | catalogued as COSV100442921, COSV100442952; called by muse, mutect2, varscan2
- OTUD5 | c.1647C>T p.S549= | Silent (SNP) | VAF 74/183 reads (40%) | catalogued as COSV99331983; called by muse, mutect2, varscan2
- PKNOX2 | c.111C>G p.P37= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV100020879; called by muse, mutect2
- PPCS | c.126A>C p.S42= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100999502; called by muse, mutect2, varscan2
- SIRT2 | c.552G>T p.V184= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV99979424; called by muse, mutect2, varscan2
- TMEM182 | c.528C>T p.D176= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV101305391; called by muse, mutect2, varscan2
- UCK2 | c.621C>T p.I207= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV63314368; called by muse, mutect2
- IGHM | c.1300+56C>A | Intron (SNP) | VAF 125/648 reads (19%) | called by muse, mutect2, varscan2
